CPTAC case C3L-03639 — Pancreas — Ductal and Lobular Neoplasms (CPTAC-3)
Open-access clinical record from the NCI Genomic Data Commons (Data Release 46.0 - August 10, 2026), part of the Clinical Proteomic Tumor Analysis Consortium (CPTAC). Disease type: Ductal and Lobular Neoplasms; Primary site: Pancreas. Index date (day 0 for every day count below): diagnosis.
https://portal.gdc.cancer.gov/cases/0b2f0141-88e1-4117-a668-f284ec7670ff

Demographics
Sex at birth: male; Year of birth: 1942; Vital status: Dead; Days to death: 246 days; Year of death: 2019; Cause of death: Cancer Related.

Diagnoses (1)
1. Infiltrating duct carcinoma, NOS: ICD-O-3 morphology code: 8500/3; Tissue or organ of origin: Pancreas, NOS; Site of resection or biopsy: Head of pancreas; Age at diagnosis: 76.0 years (27,761 days); Year of diagnosis: 2018; AJCC staging edition: 8th; AJCC clinical M: M0; AJCC pathologic T: T2; AJCC pathologic N: N0; AJCC pathologic M: M0; AJCC pathologic stage: Stage IB; Tumor grade: G3; Residual disease: R0; Last known disease status: With tumor; Days to last known disease status: 246 days; Progression or recurrence: yes; Days to recurrence: 169 days; Days to last follow up: 246 days; Tumor focality: Unifocal.
   Pathology details: Greatest tumor dimension: 3.9 cm; Lymph node involvement: Negative; Lymph nodes positive: 0; Lymph nodes tested: 13; Lymphatic invasion present: Yes; Margin status: Uninvolved; Perineural invasion present: Yes; Vascular invasion present: Yes.
   Chemotherapy — whether it was given is not recorded by GDC; Treatment outcome: Complete Response.

Follow-up (1 entry)
- Days to follow up: 246 days; Disease response: Progressive Disease; Progression or recurrence: Yes; Days to recurrence: 169 days; Karnofsky performance status: 70; ECOG performance status: 2.

Other clinical attributes
- Weight: 65.8 kg; Height: 159 cm; BMI: 26.03.

Exposures
- Tobacco smoking status: Lifelong Non-Smoker; Alcohol history: Yes; Alcohol intensity: Not Heavy Drinker.

Biospecimens (4 samples; slide percentages are pathologist estimates recorded by GDC per slide)
- Sample C3L-03639-01: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Biospecimen anatomic site: Pancreas; Preservation method: Snap Frozen; Freezing method: LN2; Days to sample procurement: 0 days; Initial weight: 135.6 mg; Time between excision and freezing: 39 minutes; Method of sample procurement: Tumor Resection; Diagnosis pathologically confirmed: Yes.
  Slide C3L-03639-21: Section location: Head; Percent tumor nuclei: 50; Percent necrosis: 0.
- Sample C3L-03639-02: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Biospecimen anatomic site: Pancreas; Preservation method: Snap Frozen; Freezing method: LN2; Days to sample procurement: 0 days; Initial weight: 105.8 mg; Time between excision and freezing: 39 minutes; Method of sample procurement: Tumor Resection; Diagnosis pathologically confirmed: Yes.
  Slide C3L-03639-22: Section location: Head; Percent tumor nuclei: 50; Percent necrosis: 10.
- Sample C3L-03639-03: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Biospecimen anatomic site: Pancreas; Preservation method: Snap Frozen; Freezing method: LN2; Days to sample procurement: 0 days; Initial weight: 144.6 mg; Time between excision and freezing: 39 minutes; Method of sample procurement: Tumor Resection; Diagnosis pathologically confirmed: Yes.
  Slide C3L-03639-23: Section location: Head; Percent tumor nuclei: 50; Percent necrosis: 20.
- Sample C3L-03639-31: Sample type: Blood Derived Normal; Tissue type: Normal; Specimen type: Peripheral Blood Components NOS; Biospecimen anatomic site: Blood; Preservation method: Frozen; Freezing method: -20 (unit not recorded by GDC); Days to sample procurement: 0 days; Method of sample procurement: Blood Draw.
